Somatic mutation profile of tumor specimen C3N-01856-03 (aliquot CPT0162100006) from CPTAC case C3N-01856, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 66.4 years (24,242 days).
Specimen C3N-01856-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Occipital Cortex; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 36302a3c-2f7c-4874-bab6-43fd02ec8b03.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01856-31 (Blood Derived Normal), aliquot CPT0162120002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/88ad07e5-4cb0-46cd-bee4-42ef529b0407

The open-access MAF lists 83 somatic variants for this specimen: 55 protein-altering or splice-affecting, 19 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 51, Silent 19, Intron 7, Frame Shift Del 4, 5'Flank 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC3 | c.142G>A p.A48T | Missense Mutation (SNP) | VAF 75/356 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs757334041, COSV53332555; called by muse, mutect2, varscan2
- CATSPER4 | c.566G>A p.R189H | Missense Mutation (SNP) | VAF 84/357 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs199726912; called by muse, mutect2, varscan2
- CPT1B | c.1241G>A p.R414H | Missense Mutation (SNP) | VAF 28/107 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.849); catalogued as rs757229551, COSV56415320; called by muse, mutect2, varscan2
- CTSG | c.244C>T p.R82W | Missense Mutation (SNP) | VAF 90/340 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.776); catalogued as COSV53534971; called by mutect2, varscan2
- FAM71E1 | c.482C>T p.P161L (on ENST00000600100 / NM_001308429.2; = p.P145L on NM_138411.3) | Missense Mutation (SNP) | VAF 25/105 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs763452397; called by muse, mutect2, varscan2
- FRAS1 | c.4007C>T p.S1336L | Missense Mutation (SNP) | VAF 57/189 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.062); catalogued as rs746766578, COSV53625416; called by muse, mutect2, varscan2
- HS3ST1 | c.67G>A p.A23T | Missense Mutation (SNP) | VAF 27/117 reads (23%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs1026245053, COSV99137108; called by muse, mutect2, varscan2
- IFT172 | c.4697G>A p.R1566H | Missense Mutation (SNP) | VAF 43/211 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs915032282; called by muse, mutect2, varscan2
- JAK1 | c.2170C>T p.R724C | Missense Mutation (SNP) | VAF 75/332 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1307956862, COSV61090721; called by muse, mutect2, varscan2
- LRGUK | c.740A>T p.N247I | Missense Mutation (SNP) | VAF 26/159 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV53643872; called by muse, mutect2, varscan2
- MAN1C1 | c.592del p.E198Nfs*5 | Frame Shift Del (DEL) | VAF 73/308 reads (24%) | catalogued as COSV56045185; called by mutect2, pindel, varscan2
- MCOLN2 | c.245G>A p.R82H | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.374); catalogued as rs368881560; called by muse, mutect2, varscan2
- MFSD13A | c.1385C>T p.T462M | Missense Mutation (SNP) | VAF 48/146 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as rs201731359; called by muse, mutect2, varscan2
- MPO | c.1093G>A p.V365I | Missense Mutation (SNP) | VAF 88/392 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.019); catalogued as rs1446697754, COSV99832368; called by muse, mutect2, varscan2
- MYO5B | c.1706G>T p.R569I | Missense Mutation (SNP) | VAF 109/389 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.164); catalogued as COSV53234249; called by muse, mutect2, varscan2
- OBSCN | c.17552C>T p.A5851V | Missense Mutation (SNP) | VAF 29/116 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as rs757097064; called by muse, mutect2, varscan2
- OR13C3 | c.793C>T p.R265C | Missense Mutation (SNP) | VAF 62/240 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.035); catalogued as rs369932733; called by muse, mutect2, varscan2
- OR4S2 | c.359G>A p.R120H | Missense Mutation (SNP) | VAF 38/165 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.015); catalogued as rs772133654, COSV56746431; called by muse, mutect2, varscan2
- OR52N4 | c.397C>T p.R133C | Missense Mutation (SNP) | VAF 76/288 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.028); catalogued as rs753229074; called by muse, mutect2, varscan2
- PAX5 | c.1088C>T p.P363L | Missense Mutation (SNP) | VAF 35/101 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1166397855, COSV100814680, COSV63904768; called by muse, mutect2, varscan2
- PRR27 | c.55C>T p.R19W | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as rs577881430, COSV60641128; called by muse, mutect2, varscan2
- RIMBP2 | c.2846G>A p.R949H | Missense Mutation (SNP) | VAF 85/373 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs150099064; called by muse, mutect2, varscan2
- RNF19A | c.1345G>A p.V449I | Missense Mutation (SNP) | VAF 46/124 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); catalogued as rs767726348, COSV61993824; called by muse, mutect2, varscan2
- RYR1 | c.3251G>A p.S1084N | Missense Mutation (SNP) | VAF 155/685 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.9); catalogued as rs777170044; called by muse, mutect2, varscan2
- SEMA3C | c.1903G>T p.G635C | Missense Mutation (SNP) | VAF 76/307 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.586); catalogued as rs1179427222, COSV54855288; called by muse, mutect2, varscan2
- SGCD | c.790G>A p.V264I (on ENST00000435422 / NM_001128209.2; = p.V265I on NM_000337.5) | Missense Mutation (SNP) | VAF 36/120 reads (30%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.984); catalogued as rs772185467, COSV100550976, COSV61903379; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SIN3A | c.2660A>G p.Y887C | Missense Mutation (SNP) | VAF 102/334 reads (31%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.682); catalogued as rs752355034; called by muse, mutect2, varscan2
- SLC28A2 | c.31G>T p.A11S | Missense Mutation (SNP) | VAF 56/240 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs867705406; called by muse, mutect2, varscan2
- SPHKAP | c.414T>G p.N138K | Missense Mutation (SNP) | VAF 44/140 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.814); catalogued as COSV100764296; called by muse, mutect2, varscan2
- TFAP2D | c.710G>A p.R237H | Missense Mutation (SNP) | VAF 55/203 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs769871422, COSV50457626; called by muse, mutect2, varscan2
- TGFBI | c.1022G>C p.G341A | Missense Mutation (SNP) | VAF 66/352 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100526198, COSV59352104; called by muse, mutect2, varscan2
- UNC79 | c.6315T>A p.D2105E (on ENST00000393151 / NM_001346218.2; = p.D1928E on NM_020818.5) | Missense Mutation (SNP) | VAF 63/244 reads (26%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.85); catalogued as COSV56371972; called by muse, mutect2, varscan2
- USH2A | c.5842C>T p.R1948C | Missense Mutation (SNP) | VAF 121/386 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs145647517; called by muse, mutect2, varscan2
- ZFR2 | c.916G>A p.V306M | Missense Mutation (SNP) | VAF 91/367 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0.011); catalogued as rs758661848, COSV99507682; called by muse, mutect2, varscan2
- ZNF541 | c.901G>A p.E301K | Missense Mutation (SNP) | VAF 49/155 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.656); catalogued as COSV99645305; called by muse, mutect2, varscan2
- CCSER1 | c.1428A>T p.K476N | Missense Mutation (SNP) | VAF 57/281 reads (20%) | SIFT tolerated (0.56); PolyPhen benign (0.163); called by muse, mutect2, varscan2
- CLSPN | c.3518G>C p.R1173T | Missense Mutation (SNP) | VAF 60/217 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DLEC1 | c.573_594del p.R193Cfs*7 | Frame Shift Del (DEL) | VAF 42/221 reads (19%) | called by mutect2, pindel, varscan2
- GRIP2 | c.536G>T p.G179V (on ENST00000619221; = p.G82V on NM_001080423.4) | Missense Mutation (SNP) | VAF 37/147 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IFIT1 | c.111C>G p.N37K | Missense Mutation (SNP) | VAF 68/171 reads (40%) | SIFT tolerated (0.28); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- KCNN1 | c.979A>T p.T327S | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- LRP1B | c.3025A>T p.N1009Y | Missense Mutation (SNP) | VAF 26/149 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- LRP1B | c.2670G>C p.Q890H | Missense Mutation (SNP) | VAF 62/228 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.81); called by muse, mutect2, varscan2
- NDUFA4 | c.93_94del p.Y32Sfs*17 | Frame Shift Del (DEL) | VAF 50/241 reads (21%) | called by mutect2, pindel, varscan2
- OPN5 | c.463G>C p.A155P | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.438); called by muse, mutect2
- OR4C11 | c.281A>T p.E94V | Missense Mutation (SNP) | VAF 72/192 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.432); called by muse, mutect2, varscan2
- OSBP | c.1253A>G p.N418S | Missense Mutation (SNP) | VAF 55/249 reads (22%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- RPL7A | c.377G>A p.G126E | Missense Mutation (SNP) | VAF 65/269 reads (24%) | SIFT tolerated (0.51); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- SACS | c.880G>C p.E294Q | Missense Mutation (SNP) | VAF 81/351 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.355); called by muse, mutect2, varscan2
- SLC37A3 | c.542T>A p.L181H | Missense Mutation (SNP) | VAF 51/274 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, varscan2
- TGIF2LY | c.524G>A p.R175Q | Missense Mutation (SNP) | VAF 183/373 reads (49%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); called by muse, mutect2, varscan2
- TTN | c.23699G>A p.C7900Y (on ENST00000591111; = p.C6973Y on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 56/244 reads (23%) | PolyPhen benign (0.012); called by muse, mutect2, varscan2
- UGT1A1 | c.959T>C p.M320T | Missense Mutation (SNP) | VAF 90/330 reads (27%) | SIFT tolerated (0.54); PolyPhen benign (0.141); called by muse, mutect2, varscan2
- ZNF219 | c.1523G>A p.R508H | Missense Mutation (SNP) | VAF 25/93 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- ZRSR2 | c.115_116del p.D39Lfs*15 | Frame Shift Del (DEL) | VAF 40/142 reads (28%) | called by pindel, varscan2
- ARHGAP30 | c.3117C>A p.I1039= (on ENST00000368013 / NM_001025598.2; = p.I828= on NM_181720.3) | Silent (SNP) | VAF 27/74 reads (36%) | called by muse, mutect2, varscan2
- CALCR | c.1356C>T p.G452= (on ENST00000649521 / NM_001164737.2; = p.G436= on NM_001742.4) | Silent (SNP) | VAF 39/272 reads (14%) | catalogued as rs751428108, COSV100810434; called by muse, mutect2, varscan2
- CALML5 | c.6C>T p.A2= | Silent (SNP) | VAF 26/70 reads (37%) | catalogued as rs528194668; called by muse, mutect2
- CAPN8 | c.600A>T p.T200= | Silent (SNP) | VAF 27/131 reads (21%) | called by muse, mutect2, varscan2
- COL3A1 | c.1785A>G p.E595= | Silent (SNP) | VAF 120/444 reads (27%) | called by muse, varscan2
- FOS | c.1128G>A p.T376= | Silent (SNP) | VAF 30/144 reads (21%) | catalogued as rs777597151; called by muse, mutect2
- INAVA | c.459G>A p.A153= | Silent (SNP) | VAF 25/120 reads (21%) | catalogued as rs773964932, COSV66256004; called by muse, mutect2, varscan2
- LOX | c.1128A>T p.L376= | Silent (SNP) | VAF 20/62 reads (32%) | called by muse, mutect2, varscan2
- LRRC8E | c.1902G>A p.T634= | Silent (SNP) | VAF 67/210 reads (32%) | catalogued as rs751696623; called by muse, mutect2, varscan2
- MAST2 | c.1218G>T p.V406= | Silent (SNP) | VAF 67/220 reads (30%) | called by muse, mutect2, varscan2
- NLRC3 | c.2022G>A p.A674= | Silent (SNP) | VAF 31/142 reads (22%) | catalogued as rs748215521, COSV57087877; called by muse, mutect2, varscan2
- PTCHD3 | c.1005C>T p.Y335= | Silent (SNP) | VAF 91/241 reads (38%) | catalogued as rs757642564, COSV71256434; called by muse, mutect2, varscan2
- RELN | c.7986C>T p.G2662= | Silent (SNP) | VAF 124/628 reads (20%) | called by muse, mutect2, varscan2
- SDS | c.384G>A p.P128= | Silent (SNP) | VAF 10/31 reads (32%) | catalogued as rs941702914, COSV57452960, COSV99981094; called by muse, mutect2, varscan2
- TRPV5 | c.1680C>T p.F560= | Silent (SNP) | VAF 79/403 reads (20%) | catalogued as rs748628187, COSV99520707; called by muse, mutect2, varscan2
- TTN | c.2397G>A p.T799= (on ENST00000591111; = p.T753= on NM_003319.4) | Silent (SNP) | VAF 92/364 reads (25%) | catalogued as rs369313128; ClinVar: likely benign; called by muse, mutect2, varscan2
- VIT | c.1584C>T p.S528= (on ENST00000389975 / NM_001177969.1; = p.S543= on NM_053276.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 50/201 reads (25%) | catalogued as rs1443611805, COSV64896545; called by muse, mutect2, varscan2
- VPS8 | c.3678A>G p.E1226= (on ENST00000625842 / NM_001349294.1; = p.E1224= on NM_015303.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 24/72 reads (33%) | called by muse, mutect2, varscan2
- ZFYVE26 | c.7521C>T p.A2507= | Silent (SNP) | VAF 144/583 reads (25%) | catalogued as rs745599153; called by muse, mutect2, varscan2
- ALKBH8 | chr11:107565631 A>G | 5'Flank (SNP) | VAF 60/358 reads (17%) | called by muse, mutect2, varscan2
- CLUHP11 | n.727T>A | RNA (SNP) | VAF 58/263 reads (22%) | called by muse, mutect2, varscan2
- FMN1 | c.3929-6705C>T | Intron (SNP) | VAF 66/321 reads (21%) | catalogued as rs777106275; called by muse, mutect2, varscan2
- GK5 | c.1144-699G>A | Intron (SNP) | VAF 5/62 reads (8%) | catalogued as rs914524308; called by muse, mutect2
- KDM6A | c.2939-42A>G | Intron (SNP) | VAF 45/66 reads (68%) | called by muse, mutect2, varscan2
- RAPGEF6 | c.3746-2643A>G | Intron (SNP) | VAF 79/331 reads (24%) | called by muse, mutect2, varscan2
- TRDN | c.931+13T>G | Intron (SNP) | VAF 42/103 reads (41%) | called by muse, mutect2, varscan2
- VOPP1 | c.54+10317C>T | Intron (SNP) | VAF 3878/4032 reads (96%) | called by muse, mutect2, varscan2
- ZNF695 | c.259+3281A>G | Intron (SNP) | VAF 44/183 reads (24%) | called by muse, mutect2, varscan2
